Somatic mutation profile of tumor specimen 1105234 (aliquot 7316UP-553-1105234) from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen 1105234: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fe0ca4d-bc01-4b38-8da2-a2722c0b7d62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105287 (Blood Derived Normal), aliquot 7316UP-393-1105287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/109fec1e-aa3a-4f2b-86dd-2709797695a7

The open-access MAF lists 1,116 somatic variants for this specimen: 787 protein-altering or splice-affecting, 212 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 664, Silent 212, Nonsense Mutation 59, Intron 52, Frame Shift Del 24, 5'UTR 20, 3'UTR 19, Splice Site 16, RNA 16, Splice Region 11, 5'Flank 8, Frame Shift Ins 7.

Variants (750 of 1,116; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 33/142 reads (23%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 138/737 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs797045203, CM139760, COSV55671915, COSV55675820, COSV55678737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 186/586 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.3857G>C p.S1286T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100383745; called by muse, mutect2, varscan2
- ACHE | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814894; called by muse, mutect2, varscan2
- ADCY8 | c.1639G>T p.G547W | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53915654; called by muse, mutect2
- AGBL3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51954764; called by muse, mutect2
- ALOXE3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 173/501 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs372027737; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- APAF1 | c.2834G>T p.R945L (on ENST00000551964 / NM_181861.2; = p.R891L on NM_001160.3) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs146420669; called by muse, mutect2, varscan2
- AR | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1305696138; called by muse, mutect2, varscan2
- ARMC5 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 89/639 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182126474, COSV99192819; called by muse, mutect2, varscan2
- ASCC3 | c.6275G>T p.G2092V | Missense Mutation (SNP) | VAF 91/334 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100976164; called by muse, mutect2, varscan2
- ASTN2 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100528087; called by muse, mutect2, varscan2
- ATP2A2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875265, COSV57876016; called by muse, mutect2, varscan2
- ATXN1 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV55207534; called by muse, mutect2, varscan2
- AXDND1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV62641362; called by muse, mutect2
- B4GALT1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1177565118, COSV65709015; called by muse, mutect2, varscan2
- BCL6 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51656145; called by muse, mutect2, varscan2
- BIN1 | c.1397G>C p.G466A (on ENST00000316724 / NM_001320642.1; = p.G327A on NM_004305.4) | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs762512900; called by muse, mutect2, varscan2
- BRINP1 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56302494, COSV56307679; called by muse, mutect2, varscan2
- BTBD11 | c.3138C>G p.C1046W (on ENST00000280758 / NM_001018072.2; = p.C583W on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55028759; called by muse, mutect2
- BTBD11 | c.3139G>A p.E1047K (on ENST00000280758 / NM_001018072.2; = p.E584K on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs34000924; called by muse, mutect2, varscan2
- C1orf87 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs750065570; called by muse, mutect2, varscan2
- CACNA2D1 | c.1590G>C p.K530N | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV62385745; called by muse, mutect2, varscan2
- CACNA2D1 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62371428; called by muse, mutect2, varscan2
- CAMKK1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | catalogued as COSV50126407; called by muse, mutect2
- CCDC168 | c.14264C>A p.P4755Q | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV59423319; called by muse, mutect2, varscan2
- CCDC171 | c.2443A>C p.K815Q | Missense Mutation (SNP) | VAF 172/481 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756614235; called by muse, mutect2, varscan2
- CD6 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs371896389; called by muse, mutect2
- CDH23 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 47/231 reads (20%) | catalogued as CM118623; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100575746; called by muse, mutect2, varscan2
- CEBPB | c.263del p.P88Rfs*53 | Frame Shift Del (DEL) | VAF 58/283 reads (20%) | catalogued as rs1213951106; called by mutect2, pindel, varscan2
- CFAP61 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV55621866; called by muse, mutect2, varscan2
- CFAP69 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60188600; called by muse, mutect2, varscan2
- CHCHD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 38/155 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs756273254; called by muse, mutect2, varscan2
- CHGB | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as rs560272361, COSV66760876; called by muse, mutect2
- CHRM3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs202097685, COSV55093350, COSV99697259; called by muse, varscan2
- CNTNAP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70502012; called by muse, mutect2, varscan2
- COL11A1 | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 237/782 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100615438; called by muse, mutect2, varscan2
- COL19A1 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 171/421 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.247); catalogued as COSV100505503, COSV59572208; called by muse, mutect2, varscan2
- COL22A1 | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV57335844; called by muse, mutect2, varscan2
- COL6A5 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339825242; called by muse, mutect2, varscan2
- COL9A3 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59654062; called by muse, mutect2, varscan2
- CPED1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100119808; called by muse, mutect2, varscan2
- CSMD1 | c.3002C>A p.T1001N (on ENST00000520002; = p.T1000N on NM_033225.6) | Missense Mutation (SNP) | VAF 114/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59294813; called by muse, mutect2, varscan2
- CTU1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1396291989; called by muse, mutect2
- CUX2 | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55627940, COSV55628772; called by muse, mutect2, varscan2
- CXorf66 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as COSV100983798; called by muse, mutect2, varscan2
- CYLC1 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751615222; called by muse, mutect2
- DLGAP1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752354203; called by mutect2, varscan2
- DMBT1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs758442204; called by muse, mutect2, varscan2
- DMXL1 | c.8329C>T p.Q2777* | Nonsense Mutation (SNP) | VAF 110/308 reads (36%) | catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- DNAH7 | c.5764-1G>T p.X1922_splice | Splice Site (SNP) | VAF 44/178 reads (25%) | catalogued as COSV56751522; called by muse, mutect2, varscan2
- DNAJB4 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1352636432; called by muse, mutect2, varscan2
- DYSF | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053212, COSV50483645; called by muse, mutect2, varscan2
- EDIL3 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99676277; called by muse, mutect2, varscan2
- EFR3B | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV104391905; called by muse, mutect2, varscan2
- EML3 | c.1978G>T p.G660W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604182; called by muse, mutect2, varscan2
- EPO | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773297902; called by muse, mutect2
- ERICH3 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV58605596; called by muse, mutect2, varscan2
- ETS2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1411415689; called by muse, mutect2, varscan2
- EVX1 | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99764062; called by muse, mutect2, varscan2
- EZHIP | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100539677; called by muse, mutect2, varscan2
- F5 | c.4375G>C p.D1459H | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63123687, COSV63129999; called by muse, mutect2, varscan2
- F9 | c.1070del p.G357Efs*11 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs1198183173, CM094094, CM940636, CM990576; called by mutect2, pindel, varscan2
- FAM135B | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777900338, COSV52730648; called by muse, mutect2, varscan2
- FAM151B | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1304437732; called by muse, mutect2
- FAM47C | c.2288G>T p.R763L | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100792410; called by muse, mutect2, varscan2
- FBXO40 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57524332; called by muse, mutect2, varscan2
- FYB1 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60952116; called by muse, mutect2, varscan2
- GAD2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1243932259, COSV99393155; called by muse, mutect2, varscan2
- GBA3 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV72438551; called by muse, mutect2, varscan2
- GBP3 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334251131; called by muse, mutect2
- GDPD4 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1034560793, COSV60016915, COSV60018216; called by muse, mutect2, varscan2
- GHR | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100050195; called by muse, mutect2, varscan2
- GRM8 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58808223; called by muse, mutect2, varscan2
- GUCY2D | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs750895890; called by muse, mutect2, varscan2
- GYS2 | c.1425G>A p.V475= | Splice Region (SNP) | VAF 38/307 reads (12%) | catalogued as COSV53925751; called by muse, mutect2, varscan2
- HEPHL1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890126; called by muse, mutect2, varscan2
- HERC1 | c.14123G>C p.W4708S | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as COSV71250596; called by muse, mutect2, varscan2
- HS6ST3 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs141432230; called by muse, mutect2, varscan2
- HSPG2 | c.10855A>C p.S3619R | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV65933030; called by muse, mutect2, varscan2
- IGLV11-55 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101135393; called by muse, mutect2
- IGSF8 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV58758476; called by muse, mutect2, varscan2
- IL21R | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 107/437 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs371591899; called by muse, mutect2, varscan2
- IL5RA | c.1061T>A p.I354N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs1204865704; called by muse, mutect2, varscan2
- INPP5D | c.2615G>T p.R872L (on ENST00000445964 / NM_001017915.3; = p.R871L on NM_005541.5) | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV64036256; called by muse, mutect2, varscan2
- IPO7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs772562320, COSV65686634; called by muse, mutect2, varscan2
- ITGA8 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 153/504 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1381764651; called by muse, mutect2, varscan2
- KCNE4 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427983334; called by muse, mutect2, varscan2
- KCNG4 | c.1264G>C p.G422R | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377056; called by muse, mutect2, varscan2
- KCNT1 | c.3010G>T p.G1004C (on ENST00000488444; = p.G1023C on NM_020822.3) | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104375601; called by muse, mutect2, varscan2
- KHDC1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1562263204; called by muse, mutect2, varscan2
- KIAA1109 | c.9407C>A p.P3136H | Missense Mutation (SNP) | VAF 180/455 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52673100; called by muse, mutect2, varscan2
- KLF7 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.327); catalogued as COSV100519073; called by muse, mutect2, varscan2
- KLHL29 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs1173388681; called by muse, mutect2, varscan2
- KNDC1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1359217204; called by muse, mutect2, varscan2
- KRT31 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV104381206; called by muse, mutect2, varscan2
- KRTAP19-1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.21); catalogued as COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- KRTAP22-2 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 62/215 reads (29%) | PolyPhen benign (0); catalogued as rs1388057362; called by muse, mutect2, varscan2
- KRTAP5-11 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100651805; called by muse, mutect2, varscan2
- KYAT3 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs769215372; called by muse, mutect2, varscan2
- LINGO4 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV59093192; called by muse, mutect2, varscan2
- LMO4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100983997; called by muse, mutect2, varscan2
- LPP | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 103/398 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs762236261; called by muse, mutect2, varscan2
- LRRC7 | c.2791C>A p.P931T (on ENST00000651989 / NM_001370785.2; = p.P898T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV99224356; called by muse, mutect2, varscan2
- MAP2 | c.3886C>G p.Q1296E | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52296184; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99151156; called by muse, mutect2, varscan2
- MARK1 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 184/446 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1165050058; called by muse, mutect2, varscan2
- MBTPS1 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570544; called by muse, mutect2, varscan2
- MEGF8 | c.8170G>A p.A2724T (on ENST00000251268 / NM_001271938.2; = p.A2657T on NM_001410.3) | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs530619835, COSV52104254; called by muse, mutect2, varscan2
- MGA | c.4031G>T p.W1344L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV54953317; called by muse, mutect2, varscan2
- MMP3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV100243024; called by muse, mutect2, varscan2
- MPIG6B | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1400142656, COSV65390338; called by muse, mutect2, varscan2
- MROH2B | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV68189770; called by muse, mutect2, varscan2
- MSH4 | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs762051663; called by muse, mutect2, varscan2
- MTTP | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748681503, COSV55507564, COSV99644913; called by muse, mutect2, varscan2
- MTUS2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101462271; called by muse, mutect2, varscan2
- MUC16 | c.41503G>T p.V13835F | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs781428326; called by muse, mutect2, varscan2
- MUC17 | c.3914C>G p.T1305S | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763406863; called by muse, mutect2, varscan2
- MUC17 | c.11123G>A p.S3708N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV60294101; called by muse, mutect2, varscan2
- MUC22 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious, low confidence (0.02); catalogued as rs1469259269; called by muse, mutect2, varscan2
- MUC5B | c.10816G>A p.G3606R | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs372672550; called by muse, mutect2
- MYBL2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 32/175 reads (18%) | catalogued as COSV53829661; called by muse, mutect2, varscan2
- MYH1 | c.5422G>T p.A1808S | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV56857151; called by muse, mutect2, varscan2
- NALCN | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as COSV51917306, COSV51932503; called by muse, mutect2, varscan2
- NAV3 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99888513; called by muse, mutect2, varscan2
- NEXMIF | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50023282; called by muse, mutect2, varscan2
- NLGN1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64349101; called by muse, mutect2, varscan2
- NLGN4X | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.333); catalogued as COSV52012012; called by muse, mutect2, varscan2
- NOTCH2 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782757612; called by muse, mutect2, varscan2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NPY2R | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV61527622; called by muse, mutect2, varscan2
- NRROS | c.1641del p.L548* | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as COSV100145401; called by mutect2, pindel*
- NTRK3 | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62296630; called by muse, mutect2
- OR10G3 | c.831del p.T278Rfs*19 | Frame Shift Del (DEL) | VAF 20/159 reads (13%) | catalogued as COSV100336118; called by mutect2, pindel, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2
- OR4K1 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99579397; called by muse, mutect2, varscan2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2
- OR9G1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56448909; called by muse, mutect2
- OSBPL5 | c.2467C>T p.L823F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as rs1227879264; called by muse, mutect2, varscan2
- PCDHGB1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs930490756; called by muse, mutect2, varscan2
- PCNT | c.6889G>A p.A2297T | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs959271732; called by muse, mutect2, varscan2
- PDE1B | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV99226348; called by muse, mutect2, varscan2
- PDP1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 91/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892212; called by muse, mutect2, varscan2
- PERM1 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.62); catalogued as rs776964907; called by muse, mutect2, varscan2
- PKHD1L1 | c.2494G>T p.G832* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV65749315; called by muse, mutect2, varscan2
- PNPLA6 | c.3112G>T p.E1038* (on ENST00000414982 / NM_001166111.2; = p.E990* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 74/249 reads (30%) | catalogued as COSV99075571; called by muse, mutect2, varscan2
- POLD1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70956804; called by muse, mutect2
- POLE4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1269666375; called by mutect2, varscan2
- PRAMEF4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 167/339 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV52437958; called by muse, mutect2, varscan2
- PRDM8 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs752993100; called by muse, varscan2
- PRDM9 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 94/526 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs184753683; called by muse, mutect2, varscan2
- PRSS58 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV73488797; called by muse, mutect2, varscan2
- PTCHD3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV71256775; called by muse, mutect2, varscan2
- RASGRF2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 90/467 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54130199; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV101208255; called by muse, mutect2, varscan2
- RNASE3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs12147890; called by muse, mutect2
- RNASE3 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV58959335; called by muse, mutect2
- ROBO2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV59922831; called by muse, mutect2, varscan2
- RP1L1 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 99/522 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101223271; called by muse, mutect2, varscan2
- RRP12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs774617555; called by muse, mutect2, varscan2
- RUFY2 | c.231del p.L78Cfs*12 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs751531309; called by mutect2, varscan2
- SALL4 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53854576; called by muse, mutect2, varscan2
- SATL1 | c.350C>A p.S117* (on ENST00000395409; = p.S304* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | catalogued as COSV60577984; called by muse, mutect2, varscan2
- SECTM1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 102/631 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1439174252; called by muse, mutect2, varscan2
- SEMA6D | c.1940G>A p.R647Q (on ENST00000316364 / NM_153618.2; = p.R585Q on NM_020858.2) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.233); catalogued as rs775757768, COSV100317124, COSV99054636; called by muse, mutect2, varscan2
- SETD1B | c.5059G>T p.G1687C | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs553963413; called by muse, mutect2, varscan2
- SH3RF3 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100514096; called by muse, mutect2
- SIGLEC7 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs771941732; called by muse, mutect2
- SLC22A25 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1272844107; called by muse, mutect2, varscan2
- SLC30A10 | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63076390; called by muse, mutect2, varscan2
- SLC35G5 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as rs764168543; called by muse, varscan2
- SLITRK2 | c.313del p.A105Hfs*5 | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | catalogued as COSV59424912; called by mutect2, pindel, varscan2
- SLITRK4 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100567516; called by muse, mutect2, varscan2
- SNTG1 | c.707T>A p.V236E | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1241317655; called by muse, mutect2, varscan2
- SPAG16 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100530410; called by muse, mutect2, varscan2
- SSX3 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53643939, COSV53646757; called by muse, mutect2, varscan2
- ST3GAL4 | c.193G>T p.D65Y (on ENST00000392669 / NM_001254758.1; = p.D61Y on NM_006278.3) | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV57109437; called by muse, mutect2, varscan2
- ST8SIA1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.174); catalogued as rs565011134; called by muse, mutect2, varscan2
- STK11 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58829789; called by muse, mutect2, varscan2
- SUGCT | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1203172280; called by muse, mutect2, varscan2
- SULF2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.774); catalogued as rs373180984; called by muse, varscan2
- SVEP1 | c.3212C>A p.S1071* | Nonsense Mutation (SNP) | VAF 50/191 reads (26%) | catalogued as COSV57029663; called by muse, mutect2, varscan2
- SYT12 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs778042037; called by muse, mutect2, varscan2
- TACO1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51976360; called by muse, mutect2, varscan2
- TBC1D1 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs151143743; called by muse, mutect2, varscan2
- TIFAB | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV72345691; called by muse, mutect2, varscan2
- TLR5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMEM161A | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50776683; called by muse, mutect2, varscan2
- TMEM178B | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV73803549; called by muse, mutect2, varscan2
- TMEM179 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs1433425536; called by muse, mutect2, varscan2
- TMPRSS11A | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV100602790; called by muse, mutect2, varscan2
- TRBV20-1 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760783607; called by muse, mutect2, varscan2
- TRIM65 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1256281792, COSV99485496; called by muse, mutect2, varscan2
- TRIM9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762640179, COSV53612436; called by muse, mutect2, varscan2
- TRPV5 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99520590; called by muse, mutect2, varscan2
- TTC29 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100283640; called by muse, mutect2
- TTLL5 | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759872181, COSV100089536; called by muse, varscan2
- TWIST1 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD013661, CD982422, CM060093; called by muse, mutect2, varscan2
- UNC45A | c.2350A>G p.M784V | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67793621; called by muse, mutect2, varscan2
- UNC5D | c.2752C>A p.L918M | Missense Mutation (SNP) | VAF 87/542 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54782165; called by muse, mutect2, varscan2
- VGLL3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs962129357; called by muse, mutect2, varscan2
- VIRMA | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99889412; called by muse, mutect2, varscan2
- WBP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776821607; called by muse, mutect2, varscan2
- WDR90 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV53471855; called by muse, varscan2
- WNK4 | c.2908G>C p.A970P | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs372187677; called by muse, mutect2
- WNT10A | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51463831; called by muse, mutect2, varscan2
- XIRP2 | c.8311G>C p.E2771Q (on ENST00000628543; = p.E2946Q on NM_152381.6) | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99737015; called by muse, mutect2, varscan2
- ZEB2 | c.1027del p.R343Efs*2 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as CM031406, COSV100356564; called by mutect2, pindel, varscan2
- ZNF134 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV68696231; called by muse, mutect2
- ZNF225 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 16/118 reads (14%) | catalogued as COSV53471936; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100835538, COSV62817472; called by muse, mutect2, varscan2
- ZNF684 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as rs1323868688; called by muse, mutect2, varscan2
- ZNF761 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV100483334; called by muse, mutect2, varscan2
- ZNF804B | c.2438A>T p.N813I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60863770; called by muse, mutect2, varscan2
- ZP3 | c.580G>A p.D194N (on ENST00000394857 / NM_001110354.2; = p.D143N on NM_007155.6) | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs753936084; called by muse, mutect2, varscan2
- AASDH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 65/189 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ABCA13 | c.14034C>A p.D4678E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCC8 | c.2872G>T p.A958S | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCG1 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 75/408 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ACTA2 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAD1 | c.306C>G p.H102Q | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM9 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2221dup p.E741Gfs*6 | Frame Shift Ins (INS) | VAF 34/199 reads (17%) | called by pindel, varscan2
- ADCY3 | c.954C>G p.V318= | Splice Region (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- ADGRB1 | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- ADGRB1 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADGRL2 | c.2555G>T p.W852L (on ENST00000370717 / NM_001366005.1; = p.W839L on NM_012302.4) | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADGRL4 | c.22+7G>T | Splice Region (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- AFF3 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AGFG1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AHCYL2 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AJAP1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- AKR1C2 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- ALDH8A1 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ALPL | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AMBP | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AMOTL2 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- AMY2B | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 136/1121 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD30A | c.4075A>T p.R1359W (on ENST00000611781; = p.R1303W on NM_052997.2) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ANKRD30BL | c.678A>C p.P226= | Splice Region (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- ANKRD60 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- AP1B1 | c.2264C>G p.A755G | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APLP2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- APLP2 | c.2107G>T p.V703L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AQP11 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- ARFIP2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP23 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP28 | c.2178A>C p.Q726H (on ENST00000383472 / NM_001366230.1; = p.Q567H on NM_001010000.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARID5B | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ARMC2 | c.567del p.S190Vfs*6 | Frame Shift Del (DEL) | VAF 59/188 reads (31%) | called by mutect2, pindel, varscan2
- ASB7 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ASIC2 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ATAD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 66/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AUTS2 | c.3133A>G p.M1045V | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BACE2 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBOX1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC6 | c.7309G>T p.D2437Y | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BPI | c.552G>T p.W184C (on ENST00000262865; = p.W180C on NM_001725.3) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BPTF | c.6508G>T p.G2170* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- BRD1 | c.2646_2649dup p.H884Tfs*9 (on ENST00000216267 / NM_001349940.1; = p.H1015Tfs*9 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 26/254 reads (10%) | called by mutect2, pindel
- BRDT | c.445+8A>T | Splice Region (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2
- BST1 | c.487T>A p.C163S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG3 | c.21del p.V8Lfs*8 | Frame Shift Del (DEL) | VAF 58/208 reads (28%) | called by mutect2, pindel
- C17orf99 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C17orf99 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 103/409 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- C20orf203 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- C8A | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C9 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- CABS1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNG5 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CALCOCO2 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CAMK4 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CAMK4 | c.1205_1212del p.K402Rfs*7 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- CASQ2 | c.1077G>C p.E359D | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2
- CASTOR2 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 123/551 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CBX2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 83/552 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CCDC105 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- CCDC166 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CCDC169 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC171 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC180 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CCDC73 | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC81 | c.917_919dup p.E306_M307insK (on ENST00000445632 / NM_001156474.2; = p.E216_M217insK on NM_021827.4) | In Frame Ins (INS) | VAF 29/174 reads (17%) | called by mutect2, pindel, varscan2
- CCL18 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCNE2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2
- CD177 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- CD274 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- CD320 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD38 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CDC14C | c.1230C>G p.Y410* (on ENST00000428251; = p.Y303* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 36/414 reads (9%) | called by muse, mutect2
- CDH4 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- CDHR2 | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CDK13 | c.2221del p.E741Kfs*27 | Frame Shift Del (DEL) | VAF 141/452 reads (31%) | called by mutect2, pindel, varscan2
- CDON | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CENPE | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- CEP350 | c.7937dup p.L2647Tfs*2 | Frame Shift Ins (INS) | VAF 20/187 reads (11%) | called by mutect2, pindel, varscan2
- CFAP46 | c.4598T>A p.L1533Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CFAP46 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP47 | c.1078_1079del p.P360Ffs*13 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- CFAP53 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- CFAP54 | c.6497G>C p.G2166A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.239); called by muse, mutect2
- CGREF1 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, varscan2
- CHAF1A | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHAT | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 106/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.4639G>A p.A1547T (on ENST00000357008 / NM_001363606.2; = p.A1560T on NM_001273.5) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD4 | c.3110G>T p.G1037V (on ENST00000357008 / NM_001363606.2; = p.G1050V on NM_001273.5) | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD8 | c.2346_2362del p.P783Efs*16 (on ENST00000646647 / NM_001170629.2; = p.P504Efs*16 on NM_020920.4) | Frame Shift Del (DEL) | VAF 64/185 reads (35%) | called by mutect2, pindel, varscan2
- CHD9 | c.8374G>T p.A2792S (on ENST00000398510 / NM_001382353.1; = p.A2776S on NM_025134.7) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CHRDL2 | c.1239G>T p.Q413H (on ENST00000376332 / NM_001304415.1; = p.D432Y on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CHRM1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHRM3 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); called by muse, varscan2
- CMKLR1 | c.631C>A p.P211T (on ENST00000312143 / NM_001142344.2; = p.P209T on NM_004072.3) | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.6571A>T p.T2191S | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CMYA5 | c.8510C>T p.P2837L | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CNGA3 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- CNGB3 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTNAP5 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL12A1 | c.5442del p.K1814Nfs*22 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- COL16A1 | c.1514A>C p.D505A | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- COL16A1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COL2A1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- COL6A6 | c.2018A>T p.E673V | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- COMMD10 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- COPS8 | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- CPEB2 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- CREM | c.729G>T p.M243I (on ENST00000429130; = p.M19I on NM_182717.2) | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRKL | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CRTAC1 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CRYBA4 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 91/503 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CRYGA | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- CSMD3 | c.8660G>T p.S2887I (on ENST00000297405 / NM_001363185.1; = p.S2718I on NM_052900.3) | Missense Mutation (SNP) | VAF 54/676 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- CSTA | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DBX2 | c.726del p.N243Ifs*16 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- DCAF17 | c.1031G>C p.W344S | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DCBLD1 | c.906_907del p.D303Qfs*2 | Frame Shift Del (DEL) | VAF 72/355 reads (20%) | called by mutect2, pindel, varscan2
- DCSTAMP | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- DDR2 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 89/454 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DDX60 | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DDX60L | c.3217A>T p.K1073* | Nonsense Mutation (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- DGKZ | c.3339G>T p.Q1113H (on ENST00000454345 / NM_001105540.2; = p.Q925H on NM_003646.4) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2
- DHX16 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DLEU7 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DLGAP3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 37/323 reads (11%) | called by muse, mutect2, varscan2
- DLGAP5 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DMXL1 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB11 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DNM3 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DOCK4 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, mutect2
- DOCK9 | c.5519G>C p.G1840A (on ENST00000376460 / NM_001366676.2; = p.G1841A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1B | c.6415G>T p.G2139W | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPEP3 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DROSHA | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 73/428 reads (17%) | called by muse, mutect2, varscan2
- DUSP3 | c.354C>T p.G118= | Splice Region (SNP) | VAF 42/273 reads (15%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- EBF1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECEL1 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ELF5 | c.91A>C p.M31L (on ENST00000312319 / NM_198381.2; = p.M21L on NM_001422.4) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.267); called by muse, mutect2
- ELP3 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EMX1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPG5 | c.6874A>T p.I2292F | Missense Mutation (SNP) | VAF 173/541 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EPG5 | c.3400A>T p.S1134C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA3 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EPS15 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ERC2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ERICH1 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESPNL | c.1882A>T p.T628S | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESX1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ETV1 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EXOC7 | c.1091A>T p.Y364F (on ENST00000335146 / NM_001145297.4; = p.Y282F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EYS | c.5520G>C p.W1840C | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EYS | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F2 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM114A1 | c.945+1G>T p.X315_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- FAM135B | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- FAM240A | c.180G>T p.K60N (on ENST00000444264; = p.K54N on NM_001195442.2) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FAM78A | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCM | c.4810G>T p.D1604Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTKD3 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2
- FAT4 | c.9285C>G p.H3095Q | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT4 | c.10204G>T p.D3402Y | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FFAR1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 105/336 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FGD5 | c.2645G>C p.S882T | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FGF23 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 100/678 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FLG2 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FLOT2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FMO4 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FOXD1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL2 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2
- FOXP2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FPGT | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2
- FRMPD4 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FRY | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- FSD2 | c.1708A>T p.K570* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- FSIP2 | c.11223T>A p.N3741K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FSIP2 | c.16468C>A p.P5490T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FSIP2 | c.17587G>C p.V5863L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FSTL5 | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- FUOM | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- GABRA6 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 44/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GABRR2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GCKR | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- GEN1 | c.2144G>T p.C715F | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJB5 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- GLE1 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 70/547 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GNRHR | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP2 | c.971T>G p.L324R (on ENST00000381362 / NM_001007240.3; = p.L321R on NM_001502.4) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR179 | c.5285C>A p.A1762D (on ENST00000621958; = p.A1761D on NM_001004334.4) | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- GRIA4 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRIN2B | c.2219C>A p.A740E | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GRM5 | c.1885T>A p.Y629N | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM7 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRM7 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- GRM8 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GTF3C4 | c.1889A>G p.Q630R | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- GZMA | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- H2AC6 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACE1 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 69/207 reads (33%) | called by muse, mutect2, varscan2
- HAVCR2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HBE1 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 34/532 reads (6%) | called by muse, mutect2
- HEATR9 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELQ | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HELZ | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HERC2 | c.5578G>T p.G1860* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- HEY1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HGFAC | c.1241C>G p.S414W | Missense Mutation (SNP) | VAF 122/562 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIBADH | c.713A>T p.K238I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- HIVEP2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HLA-DQA2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMCN2 | c.4988G>T p.G1663V | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA2 | c.391+7C>A | Splice Region (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- IGFBP2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGKV2D-24 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- IGSF9B | c.4147G>C p.V1383L | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IK | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- INHBA | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INVS | c.2132G>T p.S711I | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IRS4 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IRX2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- IRX4 | c.83A>C p.E28A | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- IRX4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 32/299 reads (11%) | called by muse, mutect2, varscan2
- ITGB8 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ITIH5 | c.1191C>G p.S397R | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ITIH6 | c.1076-2A>T p.X359_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ITIH6 | c.505del p.Q169Nfs*3 | Frame Shift Del (DEL) | VAF 81/255 reads (32%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- JCAD | c.2327C>A p.T776K | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- JSRP1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KANK1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KAT6A | c.1545del p.K516Sfs*29 | Frame Shift Del (DEL) | VAF 51/228 reads (22%) | called by mutect2, pindel, varscan2
- KCNN4 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- KIAA1841 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KIF13B | c.4001C>A p.A1334D | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIF5C | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KLF8 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL31 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL33 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2
- KLK13 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-8 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KY | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 72/441 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMA4 | c.4900A>T p.T1634S (on ENST00000230538 / NM_001105206.3; = p.T1627S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LAMA5 | c.7418A>C p.Q2473P | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LOXL3 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LRFN5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- LRFN5 | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- LRGUK | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRP2 | c.6682C>A p.L2228I | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC18 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- LRRC4C | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- LRRC4C | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- LRRC66 | c.1492G>C p.G498R | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LRRC7 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRC71 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- LRRC74B | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRC8A | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYSMD1 | c.303A>T p.E101D | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- LYSMD1 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- LYST | c.3451G>T p.V1151L | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MACF1 | c.4993G>T p.G1665C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- MAIP1 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- MAN1C1 | c.1849del p.V617* | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- MAP3K10 | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.334); called by muse, varscan2
- MBD5 | c.2845+1G>C p.X949_splice | Splice Site (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- MDH1 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- MDN1 | c.8014+1G>T p.X2672_splice | Splice Site (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- METTL17 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFRP | c.137G>T p.G46V (on ENST00000449574; = p.G422V on NM_031433.4) | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MGAM2 | c.4717C>A p.L1573I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MICAL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MKI67 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- MMP9 | c.1881C>A p.F627L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- MN1 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MPPED2 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MRC1 | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 120/582 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPL13 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- MTIF2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTUS1 | c.1893_1895dup p.A632dup | In Frame Ins (INS) | VAF 38/279 reads (14%) | called by mutect2, pindel, varscan2
- MUC12 | c.3227A>T p.Q1076L (on ENST00000379442; = p.Q933L on NM_001164462.1) | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MUC16 | c.22901G>T p.S7634I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC2 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.12); called by muse, mutect2
- MUC22 | c.4373C>G p.A1458G | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2
- MUC5AC | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); called by muse, mutect2
- MUC5B | c.11141C>G p.S3714C | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUCL1 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- MYCBPAP | c.1361A>T p.Y454F | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MYH1 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 171/349 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYH13 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 106/326 reads (33%) | called by muse, mutect2, varscan2
- MYH3 | c.3636dup p.R1213Afs*19 | Frame Shift Ins (INS) | VAF 150/508 reads (30%) | called by mutect2, pindel, varscan2
- MYLK | c.1942+4T>A | Splice Region (SNP) | VAF 87/342 reads (25%) | called by muse, mutect2, varscan2
- MYO1B | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1D | c.480C>G p.S160R | Missense Mutation (SNP) | VAF 63/517 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1G | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MYOF | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- MYOG | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYOZ1 | c.504A>G p.G168= | Splice Region (SNP) | VAF 33/211 reads (16%) | called by muse, mutect2, varscan2
- MYT1 | c.3238-1G>T p.X1080_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.3008T>A p.I1003K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF12 | c.2210A>C p.E737A | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- NCKAP5 | c.5047C>A p.L1683M | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- NCKAP5L | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2
- NDC1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, mutect2
- NDST4 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NEB | c.7802G>A p.S2601N | Missense Mutation (SNP) | VAF 102/626 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- NEFM | c.2390A>G p.K797R | Missense Mutation (SNP) | VAF 9/293 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); called by muse, mutect2
- NEK10 | c.2552C>A p.A851D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NELL1 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NEUROD1 | c.752del p.A251Efs*11 | Frame Shift Del (DEL) | VAF 102/539 reads (19%) | called by mutect2, pindel, varscan2
- NFASC | c.904C>G p.R302G (on ENST00000339876 / NM_001378329.1; = p.R313G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NFIC | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFIC | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 119/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NGF | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NKX2-5 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NLGN1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NOG | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPY5R | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NRXN3 | c.1791G>T p.E597D (on ENST00000335750 / NM_001330195.2; = p.E224D on NM_004796.6) | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NTSR1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR10AG1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10AG1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR10J1 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR10V1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR13D1 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OR1N2 | c.68G>C p.W23S | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); called by mutect2, varscan2
- OR2D2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2T6 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4C11 | c.501T>A p.C167* | Nonsense Mutation (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- OR4K17 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- OR4S2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51Q1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR5F1 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.398); called by muse, varscan2
- OR6C1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6P1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR9I1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- OR9K2 | c.364dup p.C122Lfs*15 (on ENST00000305377; = p.C100Lfs*15 on NM_001005243.1) | Frame Shift Ins (INS) | VAF 57/254 reads (22%) | called by mutect2, pindel, varscan2
- P2RY14 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALLD | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PAQR5 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PATL2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDHB10 | c.2347A>T p.R783W | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PCDHB15 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 200/670 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PCDHB3 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCLO | c.5686A>G p.T1896A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PDCD11 | c.3369-1G>T p.X1123_splice | Splice Site (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- PDCD4 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 29/272 reads (11%) | called by muse, mutect2
- PDE1C | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PDE5A | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDZRN4 | c.571del p.R191Gfs*37 | Frame Shift Del (DEL) | VAF 45/293 reads (15%) | called by mutect2, pindel, varscan2
- PEAR1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PEG3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- PEX16 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PFAS | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGK2 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2
- PIK3C3 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PIK3R2 | c.1956_1957insT p.G653Wfs*158 | Frame Shift Ins (INS) | VAF 45/140 reads (32%) | called by mutect2, pindel, varscan2
- PITRM1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD2 | c.2136G>T p.L712F | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PLA2G1B | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PLB1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- PLCB1 | c.2473A>T p.K825* | Nonsense Mutation (SNP) | VAF 31/243 reads (13%) | called by muse, mutect2, varscan2
- PLCE1 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- PLCL1 | c.470del p.K157Sfs*7 | Frame Shift Del (DEL) | VAF 39/179 reads (22%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLEC | c.10216G>T p.E3406* (on ENST00000322810 / NM_201380.4; = p.E3296* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 54/702 reads (8%) | called by muse, mutect2
- PLEKHA5 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PLEKHH2 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PLEKHO2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PLOD1 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 81/248 reads (33%) | called by muse, mutect2, varscan2
- PLOD3 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLSCR2 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- POU4F2 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- PPP1R9A | c.2833A>T p.K945* | Nonsense Mutation (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- PPRC1 | c.4756G>T p.V1586F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRF1 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRG4 | c.3677_3703del p.A1226_K1234del | In Frame Del (DEL) | VAF 72/498 reads (14%) | called by mutect2, pindel
- PRKN | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRLR | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 122/337 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRC2A | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PTBP2 | c.1390A>C p.T464P (on ENST00000426398 / NM_001300986.2; = p.T456P on NM_021190.4) | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTCD1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PTCHD4 | c.2236C>G p.Q746E | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, varscan2
- PTGIS | c.446T>A p.L149* | Nonsense Mutation (SNP) | VAF 44/285 reads (15%) | called by muse, mutect2, varscan2
- PTPN12 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PTPRA | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRB | c.3832G>C p.A1278P | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PTPRB | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PTPRH | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PTPRM | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRN | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- PTPRZ1 | c.3377A>T p.Q1126L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2
- PURG | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2, varscan2
- PXYLP1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- RAD51AP2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RADIL | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RASSF4 | c.760A>T p.R254W | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RASSF9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- RECQL4 | c.2980G>C p.D994H | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RESP18 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RGS21 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RICTOR | c.2114T>C p.L705S | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.776A>T p.Y259F (on ENST00000666250 / NM_001348490.2; = p.Y67F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RNF150 | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2
- RNF207 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RNPC3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RREB1 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RTN4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMHD1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 162/598 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAP18 | c.115C>A p.R39S (on ENST00000607003; = p.R58S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, varscan2
- SCFD2 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 26/241 reads (11%) | called by muse, mutect2, varscan2
- SCN7A | c.3000G>T p.W1000C | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN9A | c.4762A>T p.I1588F (on ENST00000303354; = p.I1577F on NM_002977.3) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- SCNN1A | c.1403A>C p.H468P | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SELENOW | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB11 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SERPINC1 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 52/294 reads (18%) | called by muse, mutect2, varscan2
- SF3A1 | c.2237A>T p.E746V | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SH2D4B | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SH3BP5L | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.4061del p.F1354Sfs*11 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- SIGLECL1 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX5 | c.1997C>G p.S666* | Nonsense Mutation (SNP) | VAF 88/464 reads (19%) | called by muse, mutect2, varscan2
- SLC16A7 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A16 | c.61_69del p.Q21_A23del | In Frame Del (DEL) | VAF 26/180 reads (14%) | called by mutect2, pindel
- SLC25A26 | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC26A9 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC27A2 | c.1458-2A>T p.X486_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- SLC35E4 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC35F3 | c.694G>T p.V232F (on ENST00000366617 / NM_001300845.1; = p.V301F on NM_173508.4) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC4A1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC4A1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 90/458 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC5A6 | c.459+1G>T p.X153_splice | Splice Site (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- SLC5A6 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLC6A12 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC6A13 | c.1582T>A p.W528R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SLC6A13 | c.1459A>T p.R487W | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC6A5 | c.877T>G p.Y293D | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMAD6 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SMARCA4 | c.4750G>T p.E1584* | Nonsense Mutation (SNP) | VAF 52/210 reads (25%) | called by muse, mutect2, varscan2
- SMC3 | c.2572G>T p.V858F | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SMG9 | c.549G>T p.L183F | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SNAI1 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNCB | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SNORC | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 37/410 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- SPATA31A1 | c.3752G>T p.R1251M | Missense Mutation (SNP) | VAF 94/599 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPEF2 | c.3378G>C p.E1126D | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SPPL2C | c.1565T>A p.L522H | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPRR2A | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SPTA1 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.225); called by muse, mutect2
- SPTBN1 | c.3093G>T p.Q1031H | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SQSTM1 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 68/665 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SRP68 | c.837G>A p.E279= | Splice Region (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- SRSF1 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SSH1 | c.2836G>T p.G946W | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSH2 | c.3550G>C p.A1184P | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5L | c.2579G>A p.G860E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SULF2 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, varscan2
- SYNDIG1L | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SYNRG | c.2800G>A p.G934S | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT13 | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TADA1 | c.816G>T p.L272F | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TBC1D32 | c.2827G>T p.E943* | Nonsense Mutation (SNP) | VAF 61/177 reads (34%) | called by muse, mutect2, varscan2
- TBCK | c.1025A>C p.N342T (on ENST00000273980 / NM_001163436.4; = p.N279T on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TBX18 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TC2N | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCAIM | c.1158T>G p.F386L | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TCERG1L | c.1210A>C p.S404R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THADA | c.5015G>T p.R1672M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.233); called by muse, mutect2
- THAP9 | c.1142A>T p.Q381L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- THNSL2 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TICRR | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- TLR10 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2
- TLX2 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMCO1 | c.31del p.A11Lfs*33 | Frame Shift Del (DEL) | VAF 44/280 reads (16%) | called by mutect2, pindel, varscan2
- TMEM121B | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TMEM174 | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TMEM223 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.509); called by mutect2, varscan2
- TMEM266 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TMEM63B | c.2112G>T p.G704= | Splice Region (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- TMPO | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 96/288 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMTC2 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 82/447 reads (18%) | called by muse, mutect2, varscan2
- TNRC6C | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TNRC6C | c.3536G>T p.G1179V | Missense Mutation (SNP) | VAF 35/510 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- TP53BP1 | c.1000A>T p.T334S | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TPBGL | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPO | c.1167C>A p.C389* | Nonsense Mutation (SNP) | VAF 85/361 reads (24%) | called by muse, mutect2, varscan2
- TRANK1 | c.5218G>T p.A1740S | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRBC2 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGV1 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TRIM49 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIO | c.7693G>T p.V2565L | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TRIP12 | c.5621G>T p.W1874L | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TROAP | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- TRPA1 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- TSGA10 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC22 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 118/652 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTF2 | c.2263A>T p.K755* | Nonsense Mutation (SNP) | VAF 18/197 reads (9%) | called by muse, mutect2
- TTN | c.60784C>A p.L20262M (on ENST00000591111; = p.L12838M on NM_003319.4) | Missense Mutation (SNP) | VAF 39/174 reads (22%) | PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TUBA8 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXLNG | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- UBE2QL1 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBQLN3 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBR5 | c.3074G>T p.S1025I | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- UBR5 | c.3073A>T p.S1025C | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
366 further variants in this file (37 protein-altering or splice-affecting, 212 silent, 117 other) are not listed here.
